Somatic mutation profile of tumor specimen TCGA-BR-8676-01A (aliquot TCGA-BR-8676-01A-11D-2394-08) from TCGA case TCGA-BR-8676, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 59.2 years (21,619 days).
Specimen TCGA-BR-8676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb3f0010-6d19-4d0e-b5e9-b4ef90907957.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8676-10A (Blood Derived Normal), aliquot TCGA-BR-8676-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e659487-cf08-4c8a-bc35-f2a146b3d5e0

The open-access MAF lists 85 somatic variants for this specimen: 63 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Nonsense Mutation 4, Frame Shift Del 4, RNA 2, Intron 1, Translation Start Site 1, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNB1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555889130, CM1511116, COSV65569863; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 80/144 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 44/78 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM18 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99695035; called by muse, mutect2, varscan2
- ADAMTS8 | c.790A>G p.N264D | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV57295423; called by muse, mutect2
- ATP7A | c.973T>A p.S325T | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV58450507; called by muse, mutect2
- CCDC183 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as rs747197488, COSV61038256; called by muse, mutect2, varscan2
- CDCP1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751386844, COSV56106937; called by muse, mutect2, varscan2
- CDH18 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs765244838, COSV56915613; called by muse, mutect2, varscan2
- CELSR3 | c.3406C>T p.Q1136* | Nonsense Mutation (SNP) | VAF 30/128 reads (23%) | catalogued as COSV50944452; called by muse, mutect2, varscan2
- CHD5 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52407559; called by muse, mutect2, varscan2
- COL1A2 | c.3208C>A p.H1070N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV51962348; called by muse, mutect2, varscan2
- CRABP2 | c.54A>T p.E18D | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63959053; called by muse, mutect2, varscan2
- DIO2 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV70445726; called by muse, mutect2, varscan2
- DPYS | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as COSV60906791; called by muse, mutect2, varscan2
- DSEL | c.2621G>A p.G874E | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765985113, COSV59493358; called by muse, mutect2, varscan2
- E2F1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs762296081, COSV55777414; called by muse, mutect2, varscan2
- EVC | c.2043G>T p.E681D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV53835807; called by muse, mutect2, varscan2
- EZH1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV70548771, COSV70550164; called by muse, mutect2, varscan2
- FAT3 | c.3253G>A p.G1085S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435628667, COSV53147085, COSV99969880; called by muse, mutect2, varscan2
- FAT4 | c.12068A>G p.D4023G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.133); catalogued as COSV58689940, COSV58698578; called by muse, mutect2, varscan2
- FRMD3 | c.148-1G>C p.X50_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100418892, COSV58465753; called by muse, mutect2, varscan2
- GABBR1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63543681, COSV99054559; called by muse, mutect2, varscan2
- GABRA6 | c.1229C>A p.A410D | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV50887066; called by muse, mutect2, varscan2
- GPR174 | c.181T>A p.L61I | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52133498; called by muse, mutect2, varscan2
- HNRNPAB | c.995A>C p.Y332S (on ENST00000504898; = p.Y285S on NM_004499.4) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57425372; called by muse, mutect2, varscan2
- IRX1 | c.846G>T p.L282F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs777640998, COSV57361122; called by muse, mutect2, varscan2
- KATNAL2 | c.1606G>A p.E536K (on ENST00000356157 / NM_001353899.1; = p.E464K on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.788); catalogued as rs762261015, COSV55293123; called by muse, mutect2, varscan2
- KCNH1 | c.857T>A p.L286H | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55069756, COSV55079390, COSV99661871; called by muse, mutect2, varscan2
- KIAA1217 | c.3860C>A p.S1287* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV56820126; called by muse, mutect2, varscan2
- KLK1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138173062; called by muse, mutect2, varscan2
- KMT2C | c.6082C>T p.R2028* | Nonsense Mutation (SNP) | VAF 36/127 reads (28%) | catalogued as rs1563288201, COSV51467980; called by muse, mutect2, varscan2
- KMT2C | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51472122; called by muse, varscan2
- KRT28 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as rs1433542157, COSV60684578; called by muse, mutect2, varscan2
- LRP1B | c.8239G>A p.D2747N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs781076753, COSV67251253; called by muse, mutect2, varscan2
- MAP9 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.077); catalogued as COSV60905616; called by muse, mutect2, varscan2
- ME2 | c.10del p.R4Gfs*2 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV58425386; called by mutect2, pindel, varscan2
- OVOL2 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs745857836, COSV99602354; called by muse, mutect2, varscan2
- PCDH10 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV52099629; called by muse, mutect2, varscan2
- PDGFRA | c.3250G>A p.V1084M | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV57271098; called by muse, mutect2
- PRDM5 | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53364079; called by muse, mutect2, varscan2
- PRXL2B | c.601A>C p.K201Q (on ENST00000444521; = p.K153Q on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV56523952; called by muse, mutect2, varscan2
- RXFP3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV57504521, COSV57508169; called by muse, mutect2, varscan2
- SCAF4 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs1247525020, COSV54587700; called by muse, mutect2, varscan2
- SEMA5A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV66800357; called by muse, mutect2, varscan2
- SIRPB1 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV53539900; called by muse, mutect2, varscan2
- SLC4A1AP | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58134345, COSV58136375; called by muse, mutect2, varscan2
- SPAM1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1285979736, COSV56144556, COSV56146044; called by muse, mutect2, varscan2
- SSPOP | n.5914C>T | Splice Region (SNP) | VAF 7/39 reads (18%) | catalogued as rs766325783, COSV50486598; called by muse, mutect2, varscan2
- STX8 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs140592918; called by muse, mutect2, varscan2
- SUSD2 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.687); catalogued as COSV100844203; called by muse, mutect2, varscan2
- SYT14 | c.1322A>C p.H441P | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55059344; called by muse, mutect2, varscan2
- TMEM229B | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62538953; called by muse, mutect2
- TRIM16L | c.782C>A p.T261K | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV67459089, COSV67459687; called by muse, mutect2, varscan2
- TUT1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV53471211; called by muse, mutect2, varscan2
- ZNF382 | c.876A>C p.E292D | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53090516; called by muse, mutect2, varscan2
- ZNF383 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs185810202; called by muse, mutect2, varscan2
- ZNF416 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV52185195; called by muse, mutect2, varscan2
- ZSCAN20 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV63683081; called by muse, mutect2, varscan2
- ANKFY1 | c.1813_1832del p.A605Wfs*6 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | called by mutect2, pindel, varscan2
- IGSF10 | c.3405del p.V1136* | Frame Shift Del (DEL) | VAF 207/441 reads (47%) | called by mutect2, pindel, varscan2
- KMT2D | c.9228dup p.N3077* | Frame Shift Ins (INS) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- ZNF107 | c.254_255del p.F85* | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- ALDH3A1 | c.816C>T p.Y272= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs553737482, COSV56734851; called by muse, varscan2
- ARHGAP21 | c.3990G>T p.T1330= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as COSV100256840, COSV57609075; called by muse, mutect2, varscan2
- ARHGAP31 | c.324T>G p.T108= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV51796401; called by muse, mutect2, varscan2
- ATP4A | c.1068C>T p.S356= | Silent (SNP) | VAF 60/181 reads (33%) | catalogued as rs1269407415, COSV52870097; called by muse, mutect2, varscan2
- COL17A1 | c.3639C>T p.I1213= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV62228261; called by muse, mutect2, varscan2
- CORO6 | c.1080C>T p.D360= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV61471577; called by muse, mutect2, varscan2
- CPS1 | c.4197C>T p.N1399= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs548201746, COSV51801812; called by muse, mutect2, varscan2
- ELL | c.1314G>A p.R438= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53214399; called by muse, mutect2
- ENGASE | c.1846C>T p.L616= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV56136762; called by muse, mutect2, varscan2
- FGA | c.765G>A p.P255= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as rs779582722, COSV57396809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD2 | c.12A>G p.L4= | Silent (SNP) | VAF 43/155 reads (28%) | catalogued as rs749411359, COSV65257190; called by muse, mutect2, varscan2
- IGSF1 | c.3823T>C p.L1275= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as COSV63838812; called by muse, mutect2, varscan2
- LIG1 | c.2325C>T p.Y775= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as rs556985324, COSV54394066; called by muse, mutect2, varscan2
- MCOLN3 | c.60C>T p.C20= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV62014370; called by muse, mutect2, varscan2
- NLRP4 | c.768G>A p.P256= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as rs140962628, COSV56713093, COSV56718330; called by muse, mutect2, varscan2
- PCDHB6 | c.747A>G p.Q249= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as COSV99169859; called by muse, mutect2
- PDE4B | c.838T>C p.L280= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV58487239; called by muse, mutect2
- PRKDC | c.8331C>T p.H2777= | Silent (SNP) | VAF 53/124 reads (43%) | catalogued as rs769525978, COSV58058849; called by muse, mutect2, varscan2
- ZFP41 | c.273G>A p.E91= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV58087841; called by muse, mutect2, varscan2
- DCHS2 | n.1365G>A | RNA (SNP) | VAF 37/163 reads (23%) | catalogued as COSV59728078, COSV59733629; called by muse, mutect2, varscan2
- IGKV1-13 | n.143A>G | RNA (SNP) | VAF 52/222 reads (23%) | called by muse, varscan2
- SLIT2 | c.1463-577G>A | Intron (SNP) | VAF 15/57 reads (26%) | catalogued as rs1459901028, COSV56566339, COSV99887535; called by muse, mutect2, varscan2
